Somatic mutation profile of tumor specimen TCGA-3N-A9WB-06A (aliquot TCGA-3N-A9WB-06A-11D-A38G-08) from TCGA case TCGA-3N-A9WB, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 72.8 years (26,602 days).
Specimen TCGA-3N-A9WB-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 24b3f2a9-c617-4a2b-8ab4-89c454e6609a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-3N-A9WB-10A (Blood Derived Normal), aliquot TCGA-3N-A9WB-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e8e8b90-280a-41c7-baa2-864739e67327

The open-access MAF lists 198 somatic variants for this specimen: 135 protein-altering or splice-affecting, 61 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 124, Silent 61, Nonsense Mutation 7, Splice Site 2, Intron 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 173/215 reads (80%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ADAM18 | c.1618C>T p.P540S | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.115); catalogued as rs767965639, COSV55844558; called by muse, mutect2
- ADAM7 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as rs137990671, COSV51537987; called by muse, mutect2, varscan2
- AGPS | c.1420C>T p.R474C | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as COSV99931272; called by muse, mutect2, varscan2
- ALPP | c.933G>A p.M311I | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV101235138; called by muse, mutect2, varscan2
- ANGPTL5 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as COSV57532658, COSV57533447; called by muse, mutect2, varscan2
- ANKS1A | c.3132+2T>G p.X1044_splice | Splice Site (SNP) | VAF 11/28 reads (39%) | catalogued as COSV100832375; called by muse, mutect2, varscan2
- ARHGEF28 | c.2741G>A p.R914Q | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1032784486, COSV55254804, COSV99708932; called by muse, mutect2, varscan2
- ASCC2 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100316234, COSV57073257; called by muse, mutect2, varscan2
- ASTN2 | c.928C>A p.R310S | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.07); catalogued as COSV100526836; called by muse, mutect2, varscan2
- ATP11B | c.1324A>C p.T442P | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.29); PolyPhen benign (0.218); catalogued as COSV100017734; called by muse, mutect2, varscan2
- ATXN2 | c.1483C>T p.P495S (on ENST00000550104; = p.P335S on NM_002973.4) | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs772982450, COSV66485255; called by muse, mutect2, varscan2
- AXDND1 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV100858355; called by muse, mutect2, varscan2
- BCL11B | c.575C>T p.S192L | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT tolerated, low confidence (0.4); PolyPhen possibly damaging (0.885); catalogued as rs560305417, COSV100595468; called by muse, varscan2
- BDKRB2 | c.173C>T p.T58I | Missense Mutation (SNP) | VAF 56/111 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV100021131; called by muse, mutect2, varscan2
- BRAF | c.2293C>T p.H765Y (on ENST00000288602 / NM_001374244.1; = p.H725Y on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56163967; called by muse, mutect2, varscan2
- C6 | c.1333C>T p.R445* | Nonsense Mutation (SNP) | VAF 52/86 reads (60%) | catalogued as rs778044260, COSV54706799; called by muse, mutect2, varscan2
- CACNA1C | c.5155C>T p.P1719S | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.979); catalogued as COSV100218230; called by muse, mutect2, varscan2
- CACNA1S | c.5608C>T p.P1870S | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV100754953; called by muse, mutect2, varscan2
- CAMSAP3 | c.1103C>T p.S368F | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); catalogued as COSV99350558; called by muse, mutect2, varscan2
- CD163L1 | c.2971C>T p.H991Y | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); catalogued as COSV100550304, COSV58018960; called by muse, mutect2, varscan2
- CD48 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as rs768191754, COSV100924223, COSV63566002; called by muse, mutect2
- CDH8 | c.1804G>A p.D602N | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.412); catalogued as rs377367876; called by muse, mutect2, varscan2
- CEMIP | c.2771G>A p.G924D | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV99586653; called by muse, mutect2, varscan2
- CFAP45 | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 91/186 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs774231764, COSV63649956; called by muse, mutect2, varscan2
- CHRNB3 | c.293G>A p.G98D | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.35); catalogued as COSV99251113; called by muse, mutect2, varscan2
- CLCA4 | c.1509G>A p.M503I | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.803); catalogued as rs761905075, COSV99760454; called by muse, mutect2, varscan2
- COL11A1 | c.5207G>A p.G1736E | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866215170, COSV100616291, COSV62179850, COSV62188136; called by muse, mutect2, varscan2
- COL4A1 | c.1289G>A p.G430E | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.936); catalogued as rs1402878630, COSV101011106; called by muse, mutect2, varscan2
- COL4A4 | c.2270G>A p.G757E | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61629944; called by muse, mutect2, varscan2
- CR1 | c.5329C>T p.P1777S | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100887564, COSV65465498; called by muse, mutect2, varscan2
- CRK | c.274C>T p.Q92* | Nonsense Mutation (SNP) | VAF 23/28 reads (82%) | catalogued as COSV100315612; called by muse, mutect2, varscan2
- CRYBG2 | c.4601G>A p.W1534* | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as COSV100366640; called by muse, mutect2, varscan2
- CTCFL | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 51/87 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs887646766, COSV99712534; called by muse, mutect2, varscan2
- DCC | c.1907C>T p.S636L | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59091921; called by muse, mutect2, varscan2
- DDX60L | c.1283C>T p.S428L | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs377140092, COSV52716054; called by muse, mutect2, varscan2
- DLL4 | c.382G>A p.D128N | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs374022749; called by muse, mutect2, varscan2
- DMBT1 | c.1675G>A p.D559N | Missense Mutation (SNP) | VAF 81/200 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV57537809; called by muse, mutect2, varscan2
- DNAH17 | c.2935G>A p.E979K | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV101102161; called by muse, mutect2
- DNAH5 | c.9320C>T p.S3107L | Missense Mutation (SNP) | VAF 64/110 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54248934; called by muse, mutect2, varscan2
- DSC3 | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV100844592; called by muse, mutect2, varscan2
- DUSP22 | c.269C>T p.A90V | Missense Mutation (SNP) | VAF 29/166 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100739725; called by muse, mutect2, varscan2
- ERBB4 | c.3650G>A p.G1217E | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765120252, COSV61478351; called by muse, mutect2, varscan2
- EVPL | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.214); catalogued as COSV100044427; called by muse, mutect2, varscan2
- FHOD3 | c.1277C>T p.S426F | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV99940934; called by muse, mutect2, varscan2
- FLG | c.6271C>T p.L2091F | Missense Mutation (SNP) | VAF 168/372 reads (45%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV100911518; called by muse, mutect2, varscan2
- FMO3 | c.1268G>A p.S423N | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as rs762744585, COSV63008774; called by muse, mutect2, varscan2
- GCKR | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as COSV99269045; called by muse, mutect2, varscan2
- GMEB1 | c.158G>A p.R53K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated, low confidence (0.68); PolyPhen possibly damaging (0.745); catalogued as COSV99603145; called by muse, mutect2, varscan2
- GPR179 | c.3779G>A p.G1260D (on ENST00000621958; = p.G1259D on NM_001004334.4) | Missense Mutation (SNP) | VAF 43/78 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.287); catalogued as rs961024732; called by muse, mutect2, varscan2
- GRIK3 | c.1127G>A p.G376E | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100901906, COSV66136884; called by muse, mutect2, varscan2
- HECW1 | c.2728C>T p.P910S | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs762517053, COSV101222903; called by muse, mutect2, varscan2
- HPD | c.557G>A p.G186E | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100000092; called by muse, mutect2, varscan2
- HS3ST1 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99136774; called by muse, mutect2, varscan2
- HTR2C | c.731A>C p.Q244P | Missense Mutation (SNP) | VAF 123/132 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV99349135; called by muse, mutect2, varscan2
- HTR4 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs755406494, COSV58805920; called by muse, mutect2, varscan2
- IGSF1 | c.2402C>A p.T801N | Missense Mutation (SNP) | VAF 57/64 reads (89%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100812057, COSV63837151; called by muse, mutect2, varscan2
- IL7R | c.801-1G>A p.X267_splice | Splice Site (SNP) | VAF 13/41 reads (32%) | catalogued as COSV100286254; called by muse, mutect2
- KALRN | c.3586G>A p.D1196N | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747383247, COSV53784747; called by muse, mutect2, varscan2
- KBTBD12 | c.1738G>A p.E580K | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.26); catalogued as COSV100675411; called by muse, mutect2, varscan2
- KCNC2 | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.012); catalogued as COSV54383000; called by muse, mutect2, varscan2
- KCNT2 | c.866G>A p.G289E | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867071033, COSV54095938; called by muse, mutect2, varscan2
- KIF21B | c.1723C>T p.Q575* | Nonsense Mutation (SNP) | VAF 82/190 reads (43%) | catalogued as rs865942025, COSV100144243; called by muse, mutect2, varscan2
- KIF3B | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1330847036, COSV100996372; called by muse, mutect2, varscan2
- KIFC1 | c.455G>A p.R152Q | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs777698079, COSV100997101; called by muse, mutect2, varscan2
- KPRP | c.17A>G p.Q6R | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.814); catalogued as COSV64221904; called by muse, mutect2, varscan2
- LRRN2 | c.1390C>T p.R464* | Nonsense Mutation (SNP) | VAF 34/80 reads (43%) | catalogued as rs777069159, COSV100912825; called by muse, mutect2, varscan2
- MAP3K15 | c.2381G>A p.G794E | Missense Mutation (SNP) | VAF 24/28 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58839665; called by muse, mutect2, varscan2
- MGA | c.4052T>A p.I1351N | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99579707; called by muse, mutect2, varscan2
- MGAM | c.3272C>T p.P1091L | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72073904; called by muse, mutect2, varscan2
- MKI67 | c.4495G>C p.D1499H | Missense Mutation (SNP) | VAF 89/186 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV100896469; called by muse, mutect2, varscan2
- MUSK | c.2171G>A p.R724Q | Missense Mutation (SNP) | VAF 55/116 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51894160; called by muse, mutect2, varscan2
- MYLIP | c.634T>A p.C212S | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.966); catalogued as COSV100785953; called by muse, mutect2, varscan2
- NCR2 | c.646G>A p.G216R | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs760606738, COSV100897218; called by muse, mutect2, varscan2
- NDST4 | c.2474G>A p.R825Q | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as rs148745383; called by muse, mutect2, varscan2
- NEIL2 | c.889G>A p.V297I | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as COSV99462225; called by muse, mutect2, varscan2
- NEUROG1 | c.684C>A p.H228Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100130780; called by muse, mutect2, varscan2
- NR4A2 | c.1345C>T p.L449F | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as rs551635594, COSV100277142; called by muse, mutect2, varscan2
- NRK | c.3130G>A p.E1044K | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV54607991; called by muse, mutect2, varscan2
- NRXN1 | c.3646C>T p.R1216C | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199888301, COSV60488178; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NXN | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.945); catalogued as rs371999469, COSV61093530; called by muse, mutect2, varscan2
- OR10H4 | c.536T>C p.F179S | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV100437715; called by muse, mutect2, varscan2
- OR13H1 | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 31/36 reads (86%) | SIFT deleterious (0.04); PolyPhen benign (0.184); catalogued as COSV100088238; called by muse, mutect2, varscan2
- OR2AK2 | c.917G>A p.G306E | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as COSV63548347; called by muse, mutect2, varscan2
- OR5B17 | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs868743937, COSV62159822; called by muse, mutect2, varscan2
- PAK5 | c.1297C>T p.R433W | Missense Mutation (SNP) | VAF 25/28 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1210292896, COSV62020757; called by muse, mutect2, varscan2
- PARP4 | c.2746C>T p.Q916* | Nonsense Mutation (SNP) | VAF 45/99 reads (45%) | catalogued as COSV101131579; called by muse, mutect2, varscan2
- PCDHAC1 | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99165950; called by muse, mutect2, varscan2
- PCDHB10 | c.2140C>T p.R714W | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99504182; called by muse, mutect2, varscan2
- PCDHB9 | c.2134C>T p.R712W | Missense Mutation (SNP) | VAF 16/289 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as rs782066746; called by muse, mutect2
- PCDHGA8 | c.724T>A p.F242I | Missense Mutation (SNP) | VAF 73/129 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); catalogued as COSV99537008; called by muse, mutect2, varscan2
- PDE11A | c.2426C>T p.S809L | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.846); catalogued as rs1011892316, COSV99612020; called by muse, mutect2, varscan2
- PDE8A | c.1648C>A p.H550N | Missense Mutation (SNP) | VAF 50/134 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV100051817; called by muse, mutect2, varscan2
- PDHA2 | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.619); catalogued as rs865933539, COSV54779463; called by muse, mutect2, varscan2
- PHYHIPL | c.743G>A p.G248E | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99513552; called by muse, mutect2, varscan2
- PI16 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.091); catalogued as COSV65448778; called by muse, mutect2, varscan2
- PLEKHG4B | c.2092G>A p.E698K (on ENST00000283426; = p.E1054K on NM_052909.5) | Missense Mutation (SNP) | VAF 19/26 reads (73%) | SIFT deleterious (0.02); PolyPhen benign (0.204); catalogued as COSV52052250, COSV99360193; called by muse, mutect2, varscan2
- PLPP4 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.581); catalogued as rs375604554; called by muse, mutect2, varscan2
- PON2 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs150924374, COSV99749651; called by muse, mutect2, varscan2
- POTED | c.273G>A p.M91I | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); catalogued as COSV100203115; called by muse, mutect2, varscan2
- PPARG | c.1427A>G p.E476G (on ENST00000287820 / NM_015869.5; = p.E446G on NM_005037.7) | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.4); catalogued as COSV99826445; called by muse, mutect2, varscan2
- PPFIA2 | c.2878G>A p.E960K | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100333103; called by muse, mutect2, varscan2
- PRAMEF12 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.075); catalogued as rs1399453753, COSV100743235; called by muse, mutect2, varscan2
- PRDM9 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs758331193, COSV57003758; called by muse, mutect2, varscan2
- PRLHR | c.304C>G p.L102V | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754917070, COSV53303905, COSV99492571, COSV99492765; called by muse, mutect2, varscan2
- PTGS2 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as rs1458352165, COSV100821739; called by muse, mutect2, varscan2
- QRICH1 | c.1337C>T p.S446L | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV100676686; called by muse, mutect2, varscan2
- RAI14 | c.1079C>T p.T360I | Missense Mutation (SNP) | VAF 31/51 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54298480, COSV99462861; called by muse, mutect2, varscan2
- ROS1 | c.5500A>C p.N1834H | Missense Mutation (SNP) | VAF 14/14 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100877010; called by muse, mutect2, varscan2
- RPE65 | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1022487798, COSV99253838; called by muse, mutect2, varscan2
- SFTPD | c.16C>T p.L6F | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as COSV100954504; called by muse, mutect2
- SIGLEC1 | c.4590C>T p.L1530= | Splice Region (SNP) | VAF 27/33 reads (82%) | catalogued as COSV99164360; called by muse, mutect2, varscan2
- SLITRK3 | c.1627C>T p.P543S | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV53850077; called by muse, mutect2, varscan2
- SNX33 | c.550A>T p.N184Y | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV100145774; called by muse, mutect2, varscan2
- SPATA2 | c.854A>C p.D285A | Missense Mutation (SNP) | VAF 64/103 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV99192795; called by muse, mutect2, varscan2
- SPATA31E1 | c.4222G>A p.E1408K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.97); PolyPhen benign (0.148); catalogued as COSV100350332; called by muse, mutect2, varscan2
- STK3 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101372509; called by muse, mutect2, varscan2
- TLE1 | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV64690125; called by muse, mutect2, varscan2
- TNFSF13B | c.767G>A p.G256E | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV101022345; called by muse, mutect2, varscan2
- TTN | c.101785G>A p.V33929I (on ENST00000591111; = p.V26505I on NM_003319.4) | Missense Mutation (SNP) | VAF 25/56 reads (45%) | PolyPhen benign (0); catalogued as rs762923784, COSV100610357; called by muse, mutect2, varscan2
- TTN | c.95971G>A p.G31991R (on ENST00000591111; = p.G24567R on NM_003319.4) | Missense Mutation (SNP) | VAF 33/79 reads (42%) | PolyPhen probably damaging (1); catalogued as COSV100610370; called by muse, mutect2, varscan2
- TTN | c.24314C>T p.T8105I (on ENST00000591111; = p.T7178I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/26 reads (54%) | PolyPhen possibly damaging (0.857); catalogued as COSV100610371; called by muse, mutect2, varscan2
- UBTF | c.1738C>T p.Q580* | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | catalogued as COSV57185215; called by muse, mutect2, varscan2
- UHRF1BP1L | c.547A>T p.I183L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.241); catalogued as COSV99691520; called by muse, mutect2, varscan2
- UPK1A | c.277G>A p.V93I | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99721853; called by muse, mutect2
- USP40 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99296306; called by muse, mutect2, varscan2
- VPS33A | c.1511C>T p.S504F | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.258); catalogued as COSV99931339; called by muse, mutect2, varscan2
- VPS36 | c.1016C>T p.S339L | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); catalogued as COSV100955183; called by muse, mutect2, varscan2
- XIRP2 | c.2807C>T p.S936L (on ENST00000628543; = p.S1111L on NM_152381.6) | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.413); catalogued as rs771644507, COSV54695141; called by muse, mutect2, varscan2
- ZNF462 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); catalogued as COSV99471636; called by muse, mutect2, varscan2
- ZNF527 | c.209A>G p.K70R | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.698); catalogued as COSV100648728; called by muse, mutect2, varscan2
- ZNF592 | c.3266C>T p.S1089F | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.568); catalogued as COSV100245835; called by muse, mutect2, varscan2
- ZNF79 | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs369378719; called by muse, mutect2, varscan2
- CD33 | c.73G>A p.V25M | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.806); called by muse, mutect2
- DDX3X | c.162dup p.D55Rfs*8 (on ENST00000399959; = p.D56Rfs*8 on NM_001356.5) | Frame Shift Ins (INS) | VAF 17/25 reads (68%) | called by mutect2, pindel, varscan2
- ADARB2 | c.1590C>T p.V530= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as COSV101186889; called by muse, mutect2, varscan2
- AFF3 | c.3090G>A p.T1030= | Silent (SNP) | VAF 36/91 reads (40%) | catalogued as rs202074625, COSV57878620; called by muse, mutect2, varscan2
- AHCTF1 | c.1101C>T p.T367= (on ENST00000366508; = p.T341= on NM_015446.5) | Silent (SNP) | VAF 35/80 reads (44%) | catalogued as COSV100403577; called by muse, mutect2, varscan2
- ANKRD30A | c.3726G>A p.T1242= (on ENST00000611781; = p.T1186= on NM_052997.2) | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs566578534, COSV64603948; called by muse, mutect2, varscan2
- ANKS1A | c.3153C>T p.I1051= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV100832377; called by mutect2, varscan2
- ATXN7L3 | c.423C>T p.D141= | Silent (SNP) | VAF 95/150 reads (63%) | catalogued as COSV101231732; called by muse, mutect2, varscan2
- AXDND1 | c.1704G>A p.G568= | Silent (SNP) | VAF 31/89 reads (35%) | catalogued as COSV100858354; called by muse, mutect2, varscan2
- B4GALNT3 | c.1068G>A p.V356= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as COSV99842912; called by muse, mutect2, varscan2
- BCAR1 | c.420C>T p.P140= | Silent (SNP) | VAF 41/113 reads (36%) | catalogued as rs970839890, COSV99366567; called by muse, mutect2, varscan2
- BEST3 | c.1968C>T p.I656= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as COSV100437729; called by muse, mutect2, varscan2
- C11orf65 | c.702G>A p.L234= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as COSV101262795; called by muse, mutect2, varscan2
- CNTRL | c.1854C>T p.I618= | Silent (SNP) | VAF 41/70 reads (59%) | catalogued as COSV99442127; called by muse, mutect2, varscan2
- COL2A1 | c.2970T>G p.G990= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV100476320; called by muse, mutect2, varscan2
- CTC1 | c.2457C>T p.L819= | Silent (SNP) | VAF 41/48 reads (85%) | catalogued as rs1042624966, COSV100236383; called by muse, mutect2, varscan2
- DLG5 | c.2475G>A p.P825= | Silent (SNP) | VAF 33/85 reads (39%) | catalogued as rs763295100, COSV100967437; called by muse, mutect2, varscan2
- DNAH5 | c.1908G>A p.R636= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs776218666, COSV54247907; called by muse, mutect2, varscan2
- DNAJB12 | c.876C>T p.L292= (on ENST00000338820; = p.L258= on NM_017626.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 28/53 reads (53%) | catalogued as rs746457201, COSV100123774, COSV58759974; called by muse, mutect2, varscan2
- DUSP22 | c.270C>T p.A90= | Silent (SNP) | VAF 29/165 reads (18%) | catalogued as rs373799515; called by muse, mutect2, varscan2
- EVPL | c.1017G>A p.Q339= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV100044429; called by muse, mutect2, varscan2
- FAM47A | c.2226C>T p.F742= | Silent (SNP) | VAF 43/47 reads (91%) | catalogued as COSV100649863, COSV60496568; called by muse, mutect2, varscan2
- FREM1 | c.6108C>T p.I2036= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs768628308, COSV66524456; called by muse, mutect2, varscan2
- FUT9 | c.81C>T p.L27= | Silent (SNP) | VAF 30/36 reads (83%) | catalogued as rs894779150, COSV56145490; called by muse, mutect2, varscan2
- GCNT1 | c.231C>T p.I77= | Silent (SNP) | VAF 32/62 reads (52%) | catalogued as COSV100946530; called by muse, mutect2, varscan2
- GNAT3 | c.951G>A p.K317= | Silent (SNP) | VAF 5/10 reads (50%) | catalogued as rs1483818862; called by muse, mutect2, varscan2
- INPP4A | c.2883C>T p.F961= (on ENST00000074304 / NM_001134224.1; = p.F922= on NM_004027.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as COSV99303536; called by muse, mutect2, varscan2
- ITSN2 | c.1536C>T p.V512= | Silent (SNP) | VAF 15/44 reads (34%) | catalogued as rs1485967392, COSV100743321; called by muse, mutect2, varscan2
- MADD | c.3775T>C p.L1259= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as COSV100211387; called by muse, mutect2, varscan2
- MDH1B | c.924G>A p.V308= | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as COSV65588648; called by muse, mutect2, varscan2
- NMUR2 | c.645C>T p.F215= | Silent (SNP) | VAF 73/123 reads (59%) | catalogued as COSV54916824; called by muse, mutect2, varscan2
- OBSCN | c.16779G>A p.E5593= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs769090423, COSV99476983; called by muse, varscan2
- OR10G8 | c.792G>A p.R264= | Silent (SNP) | VAF 46/86 reads (53%) | catalogued as rs760514680, COSV101461838, COSV70909599; called by muse, mutect2, varscan2
- OR4K14 | c.912C>T p.N304= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as COSV100520402, COSV59293107; called by muse, mutect2, varscan2
- OTOA | c.2433G>A p.R811= (on ENST00000286149; = p.R797= on NM_144672.4) | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as COSV99624384; called by muse, mutect2, varscan2
- PCDHGB2 | c.234C>T p.N78= | Silent (SNP) | VAF 69/117 reads (59%) | catalogued as rs371508602; called by muse, mutect2, varscan2
- PLEC | c.13476C>T p.A4492= (on ENST00000322810 / NM_201380.4; = p.A4382= on NM_000445.5) | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as COSV100513489; called by muse, mutect2, varscan2
- PLEKHA4 | c.2308C>T p.L770= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as COSV99612473; called by muse, mutect2, varscan2
- PLEKHM3 | c.2256C>T p.T752= | Silent (SNP) | VAF 41/104 reads (39%) | catalogued as COSV101444282; called by muse, mutect2, varscan2
- POLN | c.748T>C p.L250= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as COSV101242504; called by muse, mutect2, varscan2
- POU6F2 | c.1479C>T p.I493= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV101302632; called by muse, mutect2, varscan2
- PPP1R3B | c.153C>T p.A51= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as rs752611010, COSV100133926; called by muse, mutect2, varscan2
- PRAMEF19 | c.81C>T p.V27= | Silent (SNP) | VAF 33/70 reads (47%) | called by muse, mutect2, varscan2
- PRMT2 | c.525C>T p.H175= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV99388630; called by muse, mutect2, varscan2
- PTPN21 | c.2157C>T p.F719= | Silent (SNP) | VAF 18/26 reads (69%) | catalogued as COSV60847996; called by muse, mutect2, varscan2
- RAB13 | c.444C>T p.F148= | Silent (SNP) | VAF 37/88 reads (42%) | catalogued as COSV55132208; called by muse, mutect2, varscan2
- RETNLB | c.87C>T p.S29= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs778198277, COSV55465671; called by muse, mutect2, varscan2
- RIMBP2 | c.1014G>A p.K338= | Silent (SNP) | VAF 33/81 reads (41%) | catalogued as COSV55486680; called by muse, mutect2, varscan2
- SHISA4 | c.528C>T p.P176= | Silent (SNP) | VAF 44/116 reads (38%) | catalogued as COSV100748214; called by muse, mutect2, varscan2
- SLC38A8 | c.591C>T p.L197= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as COSV100230454; called by muse, mutect2, varscan2
- SORCS3 | c.3141C>T p.A1047= | Silent (SNP) | VAF 23/48 reads (48%) | catalogued as rs538147935, COSV100865042; called by muse, mutect2, varscan2
- SPATA31E1 | c.4221G>A p.R1407= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs1181683487, COSV100350327; called by muse, mutect2, varscan2
- SVEP1 | c.2859G>A p.L953= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV100237884; called by muse, mutect2, varscan2
- TAC1 | c.306C>T p.S102= | Silent (SNP) | VAF 17/47 reads (36%) | catalogued as COSV100071105; called by muse, mutect2, varscan2
- TARBP1 | c.1468C>T p.L490= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as COSV50183596, COSV99241536; called by muse, mutect2, varscan2
- TENM1 | c.5232C>T p.I1744= | Silent (SNP) | VAF 21/21 reads (100%) | catalogued as COSV100949854; called by muse, mutect2, varscan2
- TENM4 | c.5943C>T p.P1981= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs1255428985, COSV99573879; called by muse, mutect2, varscan2
- TEX101 | c.234G>A p.T78= (on ENST00000598265 / NM_001130011.3; = p.T96= on NM_031451.4) | Silent (SNP) | VAF 37/87 reads (43%) | catalogued as rs745685419, COSV53662545; called by muse, mutect2, varscan2
- TRAK1 | c.396C>T p.I132= (on ENST00000327628 / NM_001349247.2; = p.I74= on NM_014965.5) | Silent (SNP) | VAF 50/119 reads (42%) | catalogued as rs1294293329, COSV58257221; called by muse, mutect2, varscan2
- TRAV3 | c.120G>A p.V40= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as rs774827222; called by muse, mutect2, varscan2
- TRIOBP | c.3027C>T p.P1009= | Silent (SNP) | VAF 36/98 reads (37%) | catalogued as COSV100730821; called by muse, mutect2, varscan2
- UGT1A5 | c.516C>T p.F172= | Silent (SNP) | VAF 57/136 reads (42%) | catalogued as rs113654637, COSV100530201; called by muse, mutect2, varscan2
- VN1R2 | c.1164C>T p.F388= | Silent (SNP) | VAF 28/76 reads (37%) | catalogued as COSV59038397; called by muse, mutect2, varscan2
- BMP1 | c.2107+1843G>A | Intron (SNP) | VAF 61/97 reads (63%) | catalogued as COSV100109480; called by muse, mutect2, varscan2
- CALCR | c.52-3306C>T | Intron (SNP) | VAF 34/61 reads (56%) | catalogued as rs1269175184, COSV100810505; called by muse, mutect2, varscan2
